Somatic mutation profile of tumor specimen TCGA-AB-2943-03A (aliquot TCGA-AB-2943-03A-01W-0745-08) from TCGA case TCGA-AB-2943, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia without maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.0 years (25,568 days).
Specimen TCGA-AB-2943-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91edbb7e-447e-4d85-8b62-26b742a41ac0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2943-11A (Solid Tissue Normal), aliquot TCGA-AB-2943-11A-01W-0745-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9f3e880-dd87-409e-bff8-b3754bf70149

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 9, Silent 4, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 29/34 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP6V1C1 | c.591G>T p.W197C | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67777773; called by muse, mutect2, varscan2
- CACNA2D3 | c.2310C>A p.Y770* | Nonsense Mutation (SNP) | VAF 124/330 reads (38%) | catalogued as COSV55528335; called by muse, mutect2, varscan2
- CADPS | c.1436G>A p.R479Q | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs147388715; called by muse, mutect2, varscan2
- DESI1 | c.266C>A p.S89Y | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.496); catalogued as COSV54354237; called by muse, mutect2, varscan2
- EPHA3 | c.2872G>A p.V958M | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); catalogued as rs762601076, COSV60700684; called by muse, mutect2, varscan2
- ILRUN | c.185A>G p.Y62C | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV64989783; called by muse, mutect2, varscan2
- SERPINA12 | c.278G>A p.S93N | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as rs1466384071, COSV57942342; called by muse, mutect2, varscan2
- USP48 | c.2095G>T p.E699* | Nonsense Mutation (SNP) | VAF 78/154 reads (51%) | catalogued as COSV57608867; called by muse, mutect2, varscan2
- YEATS2 | c.3524C>T p.S1175F | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs1015632551, COSV59364056; called by muse, mutect2, varscan2
- ZNF460 | c.1104A>T p.Q368H | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV64415512; called by muse, mutect2, varscan2
- DHTKD1 | c.2211T>G p.V737= | Silent (SNP) | VAF 39/113 reads (35%) | catalogued as COSV53802740; called by muse, mutect2, varscan2
- FLT1 | c.1284C>G p.P428= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV56724445; called by muse, mutect2, varscan2
- IGKJ1 | c.40C>T p.*14= | Silent (SNP) | VAF 63/168 reads (38%) | catalogued as rs527915922; called by muse, mutect2, varscan2
- PRICKLE2 | c.2145C>T p.G715= (on ENST00000295902; = p.G659= on NM_198859.4) | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as rs376252127; called by muse, mutect2, varscan2
